Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6683, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6683-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

* Addendum *

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
Sigmoid resection for moderately differentiated adenocarcinoma at 30 cm from anal verge.

Specimens Submitted:
1: Sigmoid and upper rectum including portion of left abdominal wall, left vas deferens, left gonadal vessel, resection
2: Distal anastomotic ring
3: Proximal anastomotic ring

DIAGNOSIS:
1. Sigmoid and upper rectum including portion of left abdominal wall, left vas deferens, left gonadal vessel, resection:
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Rectosigmoid
Tumor Size:
Length is 4.0 cm
Width is 2.1 cm
Maximal thickness is 1.7 cm
Tumor Budding:
Extensive
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Tubular adenoma
Deepest Tumor Invasion:
Subserosal adipose tissue and/or mesenteric fat associated with large abscess at the tumor base; reactive changes with fibrous adhesions involve attached vas deferens and abdominal wall.
Gross Tumor Perforation:
Not identified
Lymphovascular Invasion:
Suspected
Large Venous Invasion:
Not Identified
Perineural Invasion:

** Continued on next page **

[page 2 of 5]
Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 3

Total number examined: 27

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N1b (Metastasis in 2-3 regional lymph nodes)

Comment: Immunohistochemical stains for MLH1, MSH2, MSH6 and PMS2 will be reported in an addendum.

2. Colon, distal anastomotic ring; excision:

-Benign colon.

3. Colon, proximal, anastomotic ring; excision:

-Benign colon.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	EVG	
	EVG	
	EVG	

Gross Description:

1). The specimen is received fresh and is labeled "Sigmoid and upper rectum including portion of left abdominal wall, left vas deferens, and gonadal vessel." It consists of a rectosigmoid colon that measures 29 cm in length and 8.5 cm in circumference at the distal margin. The serosal surface has a 4.5 x 4.0 x 2.5 cm soft tissue mass attached. Identified adjacent to the mass is 5.0 x 0.2 x 0.2 cm tubular structure consistent with vas deferens. The surface of the mass is inked blue, and the radial resection margin is inked black. The specimen is opened to reveal a tumor that is located 9.5 cm from the proximal margin and 13.0 cm from the distal margin. The tumor measures 4.0 cm in length and 2.1 cm in width and has raised rolled borders. Serial sectioning reveals that the tumor invades through the serosa into the

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
soft tissue mass. The tumor invasion extends to a depth of 3.0 cm, which is 0.4 cm from the surface of the soft tissue mass and 7.0 from the closest radial margin. The adipose tissue surrounding the tumor is indurated. The remaining mucosa is tan-pink with normal folds. Pericolonic and peri-rectal adipose tissue is submitted for lymph node dissection, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted. Gross photographs are taken.

Summary of sections:

PM - proximal margin
DM - distal margin
RM - radial margin
VD--possible vas deferens (block 7 possible vas deferens margin)
WM--whole mount
SM--soft tissue mass
T - tumor
A--adipose tissue adjacent to tumor
U - uninvolved mucosa
S1--serially sectioned lymph node adjacent to tumor
B1--bisected lymph node adjacent to tumor
LN - lymph nodes
BLN - bisected lymph node

2). The specimen is received in formalin, labeled "Distal anastomotic ring," and consists of a ring of pink tan soft tissue measuring 2 x 1.5 x 1 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed, and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

3). The specimen is received in formalin, labeled "Proximal anastomotic ring," and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a white plastic piece is noted. A ring of pink tan soft tissue is attached measuring 2 x 1.5 x 1 cm. The mucosal surface is pink tan and focally hemorrhagic, and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed, and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Sigmoid and upper rectum including portion of left abdominal wall,

** Continued on next page **

[page 4 of 5]
Block	Sect.	Site	PCs
2		A	4
1		B1	2
3		DM	6
7		LN	25
2		PM	4
1		RM	2
2		S1	2
3		SM	4
5		T	5
1		U	2
2		VD	4
1		WM	1

Part 2: Distal anastomotic ring

Block	Sect.	Site	PCs
1		U	1

Part 3: Proximal anastomotic ring

Block	Sect.	Site	PCs
1		U	1

Procedures/Addenda:

Addendum

Date Ordered: [REDACTED] Status: Signed Out

Date Complete: [REDACTED]

Date Reported: [REDACTED]

Addendum Diagnosis

#1) SITE: LARGE BOWEL

- Immunohistochemical stains for DNA mismatch repair proteins have been performed. The results are as follows:

MLH1: staining present in tumor

MSH2: staining present in tumor

MSH6: staining present in tumor

PMS2: staining present in tumor

Conclusion: Immunohistochemical staining for the tested DNA mismatch repair proteins is retained in the tumor.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA ' [REDACTED] as qualified to perform high complexity clinical laboratory testing.

** Continued on next page **

[page 5 of 5]
[REDACTED]

[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 2b1d4c12-ed37-4689-8adc-2d7d6b18c18e (TCGA-DC-6683.422D6524-26CD-4709-9338-960374C8C5FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).